Gene-level copy-number profile of tumor specimen MP2PRT-PAUCXR-TMP1-A from MP2PRT case MP2PRT-PAUCXR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,275 days).
Specimen MP2PRT-PAUCXR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d068293a-3f0d-4694-94cc-a21be48d17f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUCXR-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/762756ae-13c5-4d12-a5de-9c2c61c2a464

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 118; copy number 2: 706; copy number 3: 913; copy number 4: 56,252; copy number 5: 356.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:20,810,702–20,916,911, 1 gene (within-gene range 0–2): SLCO1B3.
- chr12:20,845,065–20,845,260, 1 gene (within-gene range 0–2): AC011604.1.
- chr14:22,422,371–22,479,582, 16 genes (within-gene range 0–4): TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr14:106,482,435–106,538,344, 9 genes (within-gene range 0–2): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47, IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
